Somatic mutation profile of tumor specimen TARGET-40-0A4HY5-01A (aliquot TARGET-40-0A4HY5-01A-01D) from TARGET case TARGET-40-0A4HY5, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Pelvic bones, sacrum, coccyx and associated joints; Age at diagnosis: 19.9 years (7,264 days).
Specimen TARGET-40-0A4HY5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6b4e48d8-096d-4470-827e-2dd23b331ea4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-0A4HY5-10A (Blood Derived Normal), aliquot TARGET-40-0A4HY5-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/06e64fba-0d70-4cbc-bc7a-9f49b1dcb95d

The open-access MAF lists 30 somatic variants for this specimen: 19 protein-altering or splice-affecting, 8 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 8, Frame Shift Del 2, Intron 1, RNA 1, Frame Shift Ins 1, Nonsense Mutation 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MALRD1 | c.3199dup p.M1067Nfs*5 | Frame Shift Ins (INS) | VAF 52/72 reads (72%) | catalogued as rs1272027151; called by mutect2, varscan2
- NLRP3 | c.1301C>T p.S434F | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs978050105, COSV60224249; called by muse, mutect2
- NYNRIN | c.574C>G p.L192V | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV66845708; called by muse, mutect2, varscan2
- PKD1 | c.9806G>A p.R3269Q | Missense Mutation (SNP) | VAF 57/78 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs550467690, COSV51919121; called by muse, mutect2, varscan2
- SI | c.406C>A p.P136T | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.131); catalogued as COSV52277140; called by muse, mutect2
- SIGLEC10 | c.1892C>A p.P631Q | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.017); catalogued as COSV59487597; called by muse, mutect2, varscan2
- SMC3 | c.1141C>T p.R381* | Nonsense Mutation (SNP) | VAF 24/74 reads (32%) | catalogued as COSV62423022; called by muse, mutect2, varscan2
- SZT2 | c.7571G>A p.R2524H (on ENST00000634258 / NM_001365999.1; = p.R2467H on NM_015284.4) | Missense Mutation (SNP) | VAF 100/172 reads (58%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as rs200718395; called by muse, mutect2, varscan2
- XPR1 | c.262del p.Q88Rfs*55 | Frame Shift Del (DEL) | VAF 20/63 reads (32%) | catalogued as COSV100851474; called by mutect2, varscan2
- ADGRG7 | c.2102T>G p.F701C | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2
- AKAP12 | c.4693G>A p.E1565K | Missense Mutation (SNP) | VAF 29/44 reads (66%) | SIFT deleterious (0.03); PolyPhen benign (0.415); called by muse, mutect2, varscan2
- CTC1 | c.431G>A p.C144Y | Missense Mutation (SNP) | VAF 17/153 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- FRMPD3 | c.650T>A p.F217Y | Missense Mutation (SNP) | VAF 36/52 reads (69%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- HGD | c.476del p.Q159Rfs*32 | Frame Shift Del (DEL) | VAF 16/64 reads (25%) | called by mutect2, varscan2
- IL21 | c.108G>A p.M36I | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.55); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- OR52A1 | c.130A>C p.N44H | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SCN10A | c.5780G>T p.G1927V | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- ZFHX3 | c.8899G>A p.D2967N | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2
- ZNF280C | c.1952A>G p.N651S | Missense Mutation (SNP) | VAF 15/22 reads (68%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- AQR | c.645A>C p.A215= | Silent (SNP) | VAF 6/54 reads (11%) | called by muse, mutect2
- B3GALT1 | c.306G>T p.G102= | Silent (SNP) | VAF 34/43 reads (79%) | called by muse, mutect2, varscan2
- BRINP3 | c.2286C>G p.T762= | Silent (SNP) | VAF 37/92 reads (40%) | called by muse, mutect2, varscan2
- C16orf46 | c.858C>A p.A286= | Silent (SNP) | VAF 98/125 reads (78%) | called by muse, mutect2, varscan2
- DPPA4 | c.316T>C p.L106= | Silent (SNP) | VAF 22/123 reads (18%) | called by muse, mutect2
- MALT1 | c.1131C>T p.D377= | Silent (SNP) | VAF 18/39 reads (46%) | called by muse, mutect2, varscan2
- TENM3 | c.3012C>T p.L1004= | Silent (SNP) | VAF 34/80 reads (43%) | called by muse, mutect2, varscan2
- ZFP69B | c.195C>A p.S65= | Silent (SNP) | VAF 20/77 reads (26%) | called by muse, mutect2, varscan2
- ANKRD20A8P | n.1052G>A | RNA (SNP) | VAF 78/102 reads (76%) | catalogued as rs28521748, COSV101427271; called by muse, mutect2, varscan2
- CDC16 | c.*18G>C | 3'UTR (SNP) | VAF 11/17 reads (65%) | catalogued as rs1354654333; called by muse, mutect2, varscan2
- CYP4A22 | c.1364+61T>C | Intron (SNP) | VAF 66/123 reads (54%) | called by muse, mutect2, varscan2
